Somatic mutation profile of tumor specimen 0DCM1J from CCDI case PBBMPH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 17.0 years (6,217 days).
Specimen 0DCM1J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 215d597c-11a4-4a0b-960b-afd688fe224e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM1E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/570d8549-b876-4325-812a-8f35af486e90

The open-access MAF lists 10 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, 3'UTR 2, 5'UTR 2, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT1 | c.3920A>G p.D1307G | Missense Mutation (SNP) | VAF 330/706 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, varscan2
- CXorf66 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 448/1024 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.111); called by mutect2, varscan2
- KCNA3 | c.720C>T p.S240= | Silent (SNP) | VAF 284/572 reads (50%) | catalogued as rs1557759477, COSV63901169, COSV63902208; called by mutect2, varscan2
- ZNF625 | c.1104C>T p.G368= | Silent (SNP) | VAF 160/364 reads (44%) | catalogued as rs547596088, COSV61998784; called by muse, varscan2
- ZNF862 | c.2076G>A p.V692= | Silent (SNP) | VAF 431/900 reads (48%) | catalogued as rs1307885704; called by muse, mutect2, varscan2
- LCE4A | c.*36C>T | 3'UTR (SNP) | VAF 131/270 reads (49%) | catalogued as rs769344527, COSV59266657; called by muse, mutect2, varscan2
- MDFIC | c.-1C>T | 5'UTR (SNP) | VAF 235/501 reads (47%) | catalogued as rs1398830120; called by muse, mutect2, varscan2
- NRP2 | c.251+57C>T | Intron (SNP) | VAF 275/596 reads (46%) | called by muse, mutect2, varscan2
- RRAS2 | c.-19T>G | 5'UTR (SNP) | VAF 110/236 reads (47%) | catalogued as rs1281749840; called by muse, varscan2
- TRIM51 | c.*87C>A | 3'UTR (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
